Surgical pathology report (de-identified scan), TCGA case TCGA-G7-6792, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-6792-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RENAL TUMOR
- B. FAT OVER TUMOR
- C. LEFT RENAL TUMOR
- D. LEFT RENAL TUMOR

DIAGNOSIS:

- A. LEFT KIDNEY, TUMOR, CORE BIOPSY:
- PAPILLARY RENAL CELL CARCINOMA
- B. LEFT KIDNEY, FAT OVER TUMOR, EXCISION:
- FIBROADIPOSE TISSUE, NO TUMOR SEEN
- C. LEFT KIDNEY, TUMOR MARGIN, EXCISION:
- RENAL PARENCHYMAL TISSUE WITH FOCAL CHRONIC INTERSTITIAL INFLAMMATION, NO TUMOR SEEN
- D. LEFT KIDNEY, PARTIAL NEPHRECTOMY:
- PAPILLARY RENAL CELL CARCINOMA CONFINED TO THE KIDNEY (SEE NOTE)
- FUHRMAN'S NUCLEAR GRADE 3
- TUMOR SIZE 6.2 X 4.6 X 3 CM
- RENAL PARENCHYMAL MARGIN NEGATIVE FOR TUMOR
- ADJACENT RENAL PARENCHYMA WITH ACUTE AND CHRONIC TUBULOINTERSTITIAL NEPHRITIS AND FOCAL GLOMERULOSCLEROSIS
- SIMPLE RENAL CORTICAL CYST
- SEE TEMPLATE

NOTE: The tumor exhibits a papillary growth pattern with morphologic features of types 1 and 2 and focal cytoplasmic clearing.

KIDNEY NEOPLASM TEMPLATE

Specimen type:	Left partial nephrectomy
Tumor site:	Not stated
Tumor size:	6.2 x 4.6 x 3 cm
Focality:	Unifocal (correlate with radiology)
Extent of tumor:	Limited to kidney
Histologic Types:	Papillary renal cell carcinoma (see NOTE)
Histologic Grade (Fuhrman's):	Grade 3
Invasion Vascular/Lymphatic:	Absent
Perinephric Tissue Invasion:	Absent
Margins of resection:	Parenchymal margin is negative for carcinoma
Additional pathologic findings:	Renal parenchymal tissue adjacent to tumor with acute and chronic tubulointerstitial nephritis and focal glomerulosclerosis

Pathologic Stage: pT1b Nx Mx

SPECIMEN(S):

A. RENAL TUMOR B. FAT OVER TUMOR C. LEFT RENAL TUMOR D. LEFT RENAL TUMOR

CLINICAL HISTORY:

Left kidney mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA. Renal tumor: Papillary renal cell carcinoma. By Dr., called to Dr. [REDACTED]
FSC. Left renal tumor: Benign renal parenchyma, negative for tumor. By Dr. , called to Dr. [REDACTED]

[page 2 of 2]
GROSS DESCRIPTION:**A. RENAL TUMOR**

Received fresh for frozen section are multiple cores of white-tan tissue, each measuring approximately 1.0 x 0.1 x 0.1 cm. The specimen is entirely submitted in cassette FSA1.

B. FAT OVER TUMOR

Received in formalin is a piece of yellow-pink soft tissue measuring 9.0x 5.7 x 0.5 cm. On sectioning, no masses, lesions or areas of thickening are seen. Representative sections are submitted in cassettes B1-B5.

C. LEFT RENAL TUMOR

Received fresh for frozen section are three brown pieces of renal tissue measuring 5.0 x 1.0 x 1.0 cm, 2.0 x 1.5 x 1.0 cm, and 3.5 x 2.0 x 1.0 cm. Each fragment is oriented with a stitch at the surgical margin. The margins are inked orange, blue and black, respectively. Frozen section is performed on the margins. The specimen is submitted entirely in FSC1-FSC4 (frozen section of margins) and C5-C6 (the remainder of the specimen).

D. LEFT RENAL TUMOR

Received fresh is a piece of brown-tan kidney tissue weighing 117 gm and measuring 9.0 x 5.0 x 4.0 cm. The surgical margin is inked black and the external capsular surface is inked blue. The specimen is serially sectioned to reveal a 6.2 x 4.6 x 3.0 cm tan-pink cystic friable well-circumscribed mass located 0.1 cm beneath the renal capsule. There are two cysts on the benign appearing parenchyma measuring 0.4 and 0.7 cm in greatest dimension that contain brown-gold gelatinous material. A photograph is taken and sections of the tumor are procured for the tissue bank. Representative sections are submitted in D1-D3 (one cross section including capsule and surgical margin), D4-D5 (one cross section including renal pelvis), D6-D9 (tumor), D10 (cyst), D11-D12 (normal appearing renal parenchyma).

Source: NCI Genomic Data Commons file 4d38013f-a888-4667-8bee-fa73a37452b3 (TCGA-G7-6792.B49514D6-7953-4F92-BC2F-8B72BC0156FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).